Gene-level copy-number profile of tumor specimen TCGA-D6-A6EQ-01A from TCGA case TCGA-D6-A6EQ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 57.2 years (20,876 days).
Specimen TCGA-D6-A6EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.63b02a42-e7db-440c-bb1b-87968664c956.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D6-A6EQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 831 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2f1e5542-9ccf-453d-8d79-4e9247ea55b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 324; copy number 1: 10,911; copy number 2: 42,006; copy number 3: 4,800; copy number 4: 1,336; copy number 5: 181; copy number 6: 4; copy number 7: 60; copy number 9: 60; copy number 13: 19; copy number 15: 90; copy number 24: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D6-A6EQ-01A-11D-A31K-01): tumor purity 0.39, ploidy 3.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 324 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–29,826,711, 77 genes (within-gene range 0–1) (broad region; genes not listed).
- chr16:7,004,007–7,004,112, 1 gene: RNU6-328P.
- chr16:7,301,605–7,614,992, 3 genes: AC007222.2, AC007222.1, AC005774.2.
- chr18:66,946,116–80,247,514, 208 genes (broad region; genes not listed).
- chr21:40,010,999–42,055,130, 35 genes (within-gene range 0–2): DSCAM, MIR4760, DSCAM-AS1, AF064863.1, DSCAM-IT1, AF064866.1, YRDCP3, AL773573.1, LINC00323, MIR3197, BACE2, PLAC4, BACE2-IT1, FAM3B, MX2, MX1, AP001610.2, TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT, LINC00111, LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814, PRDM15, AP001619.2, AP001619.1, AP001619.3, C2CD2, ZBTB21, ZNF295-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 415 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:94,506,766–94,507,620, 1 gene, copy number 5: ARMC10P1.
- chr7:53,926,676–56,882,146, 91 genes, copy number 15–24 (broad region; genes not listed).
- chr8:119,873,717–120,050,918, 1 gene, copy number 5 (within-gene range 2–5): DEPTOR.
- chr8:120,052,180–129,683,770, 147 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr9:33,290,512–36,487,548, 161 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr18:51,346,249–51,643,939, 1 gene, copy number 6 (within-gene range 1–6): LINC01630.
- chr18:51,612,639–51,845,628, 3 genes, copy number 6: RSL24D1P9, AC027216.1, RPS8P3.
- chr18:64,872,264–66,604,138, 10 genes, copy number 5–7: AC090348.1, AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1, CDH19.

Autosomal genes at a single copy (total copy number 1): 8,490. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
